Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A22P, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A22P-01A (Primary Tumor).

[page 1 of 3]
1CD-0-3
carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9
hw 4/26/11

Surgical Pathology Consultation Report

Patient
Name:

MRN:

DOB:

Gender: M

HCN:

Ordering

MD:

Copy To:

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Specimen(s) Received

1. Thyroid: Total thyroid stitch mark left superior pole
2. Lymph node: mediastinal nodes zone VI
3. Neck: Right neck content zone 2, 3, 4, 5

Diagnosis

1. Multifocal papillary carcinoma, dominant widely invasive classical variant, 1.2 cm, right; with a papillary microcarcinoma involving surgical margins, 1.0 cm, left; underlying mild nodular hyperplasia and focal thyroiditis: Thyroid
Metastatic papillary thyroid carcinoma: Lymph nodes, 2, isthmus and left perithyroidal
- Total thyroidectomy specimen
2. Metastatic papillary thyroid carcinoma: Lymph nodes, 5 of 6
No pathological diagnosis: Thyroid
No pathological diagnosis: Thymus
No pathological diagnosis: Parathyroid
- (Mediastinal zone VI) dissection specimen
3. Metastatic papillary thyroid carcinoma: Lymph node, 1 of 4 (right neck level II)
Metastatic papillary thyroid carcinoma: Lymph node, 1 of 4 (right neck level III)
Metastatic papillary thyroid carcinoma with focal extranodal extension: Lymph nodes, 5 of 6 (right neck level IV)
No pathological diagnosis: Lymph nodes, 6 (site not specified; received as unoriented separate tissue)
No pathological diagnosis: Soft tissue (right neck level V)
- (Right neck levels 2, 3, 4 and 5) dissection specimen

Synoptic Data

Procedure:

Other: Total thyroidectomy with right neck and mediastinal dissection specimen

Received:

Fresh

Specimen Integrity:

Fragmented

Specimen Size:

Right lobe:

4.9 cm

2.3 cm

1.0 cm

Left lobe:

[page 2 of 3]
	4.6 cm
	2.0 cm
	0.8 cm
	Isthmus +/- pyramidal lobe:
	2.0 cm
	1.5 cm
	0.5 cm
Specimen Weight:	11.6 g
Tumor Focality:	Multifocal, bilateral
----- DOMINANT TUMOR -----	
Tumor Laterality:	Right lobe
Tumor Size:	Greatest dimension: 1.2cm
	Additional dimension: 0.5 cm
	Additional dimension: 0.4 cm
Histologic Type:	Papillary carcinoma, classical (usual)
	Classical (papillary) architecture
	Classical cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	None
Tumor Capsular Invasion:	Present, extent widely invasive
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
----- SECOND TUMOR -----	
Tumor Laterality:	Left lobe
Tumor Size:	Greatest dimension: 1.0cm
	Additional dimensions: 0.5 cm
Histologic Type:	Papillary carcinoma, classical (usual)
	Papillary carcinoma, microcarcinoma (occult, small or microscopic)
	variant
	Classical (papillary) architecture
	Classical cytomorphology
Histologic Grade:	Not applicable
Margins:	Margin(s) involved by carcinoma
Tumor Capsule:	Partially encapsulated
Tumor Capsular Invasion:	Present, extent widely invasive
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Cannot be assessed
TNM Descriptors:	m (multiple primary tumors)
Primary Tumor (pT):	pT1b: Tumor more than 1 cm but not more than 2 cm in greatest dimension, limited to the thyroid
Regional Lymph Nodes (pN):	pN1b: Metastases to unilateral, bilateral or contralateral cervical or superior mediastinal lymph nodes
	Number of regional lymph nodes examined: 28
	Number of regional lymph nodes involved: 14
	Lymph Node, Extranodal Extension Present
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Adenomatoid nodule(s) or Nodular follicular disease
	Thyroiditis, focal (nonspecific)
	Parathyroid gland(s)
	Other: additional follicular variant papillary microcarcinoma, 0.1 cm, left lobe

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Comment

[page 3 of 3]
Since the surgical margins are involved by the tumor and no extrathyroidal tissue is included in this specimen, evaluation of extrathyroidal extension cannot be reliably performed on this specimen. Clinical correlation is required.

by:

Electronically verified

Gross Description

1. The specimen labeled with the patient's name and as "Thyroid: Total thyroid stitch mark left superior pole" consists of a thyroid gland that is oriented with a stitch and weighs 11.6 g. The right lobe measures 4.9 cm SI x 2.3 cm ML x 1.0 cm AP, the left lobe measures 4.6 cm SI x 2.0 cm ML x 0.8 cm AP and the isthmus measures 2.0 cm SI x 1.5 cm ML x 0.5 cm AP. The external surfaces have fibrous adhesions and are painted with silver nitrate. No parathyroid glands or no lymph nodes are identified grossly. The upper right lobe contains a well delineated nodule that measures 1.2 cm SI x 0.5 cm ML x 0.4 cm AP. The upper left lobe contains a nodular area that measures 1.0 cm SI x 0.5 cm ML x 0.4 cm. The remainder of the thyroid tissue is unremarkable. Sections of right and left lobe nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

- 1A-D right lobe, superior to inferior
- 1E-F isthmus
- 1G-K left lobe, superior to inferior

2. The specimen labeled with the patient's name and as "Lymph Node: Mediastinal nodes zone VI" consists of a piece of fibroadipose tissue that measures 2.8 x 2.5 x 1.7 cm and contains multiple lymph nodes that range from 0.5 cm to 1.2 cm. The specimen is submitted in toto as follows.

- 2A multiple lymph nodes
- 2B multiple lymph nodes
- 2C-D remainder of fatty tissue

3. The specimen labeled with the patient's name and as "Neck: Right neck content zone 2, 3, 4, 5" consists of right neck dissection with levels II-V that measures 11.0 x 8.4 x 2.4 cm and a separate piece of unoriented fatty tissue that measures 3.5 x 2.2 x 1.4 cm. Multiple lymph nodes are identified from all the levels ranging in size from 0.3 cm to 3.0 cm. One piece of tissue from the largest nodule is stored frozen. Representative sections are submitted.

- 3A one lymph node bisected level II
- 3B multiple lymph nodes level II
- 3C one lymph node bisected level III
- 3D multiple lymph nodes level III
- 3E-F largest lymph node trisected level IV
- 3G one lymph node bisected level IV
- 3H one lymph node bisected level IV
- 3I multiple lymph nodes level IV
- 3J soft tissue level V
- 3K multiple lymph nodes from the separate piece of unoriented fatty tissue
- 3L portion of unoriented fatty tissue
-

Source: NCI Genomic Data Commons file e691c7b0-01c3-4297-804c-7f8fc166d6e2 (TCGA-EM-A22P.6BF2EBFF-85D8-4F48-A68B-3DDDA60183D5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).